Somatic mutation profile of tumor specimen TARGET-30-PAPVRN-01A (aliquot TARGET-30-PAPVRN-01A-01D) from TARGET case TARGET-30-PAPVRN, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ganglioneuroblastoma; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 6.3 years (2,300 days).
Specimen TARGET-30-PAPVRN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53a9f0ac-63aa-4874-96c7-14723dbc4711.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAPVRN-10A (Blood Derived Normal), aliquot TARGET-30-PAPVRN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b1a372d8-4f65-41b2-b5a5-1db85366a67e

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXA3 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371065526; called by muse, mutect2, varscan2
- PCDHGA2 | c.2378C>T p.A793V | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs1254925291, COSV53910552; called by muse, mutect2, varscan2
- TMPRSS11A | c.481C>T p.Q161* | Nonsense Mutation (SNP) | VAF 10/102 reads (10%) | catalogued as rs1193106440; called by muse, mutect2
- ACKR2 | c.349T>G p.C117G | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CFAP43 | c.1102G>T p.V368F | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by muse, mutect2
- NPEPPS | c.2576T>A p.F859Y | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.414); called by muse, mutect2
